Somatic mutation profile of tumor specimen 1105267 (aliquot 7316UP-3213-1105267) from CPTAC case C2415597, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Temporal lobe; Tumor grade: G4.
Specimen 1105267: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 005e652c-ac46-4612-8178-ce6653688d69.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 1105205 (Blood Derived Normal), aliquot 7316UP-3213-1105205; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0d59a3d0-aa0d-4bdb-a288-5013a01fa31a

The open-access MAF lists 72 somatic variants for this specimen: 43 protein-altering or splice-affecting, 19 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, Silent 19, Intron 3, RNA 3, 5'UTR 2, Nonsense Mutation 2, Splice Site 2, 3'UTR 2, In Frame Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 19/79 reads (24%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as rs121913287, CM126688, COSV55874568, COSV55924241; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.993+1G>A p.X331_splice | Splice Site (SNP) | VAF 148/212 reads (70%) | hotspot (GDC flag); catalogued as rs11575997, CD002536, COSV52663229, COSV52699909, COSV52752826; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- CALML3 | c.92G>A p.R31H | Missense Mutation (SNP) | VAF 77/142 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs1327202118, COSV59450316; called by muse, mutect2, varscan2
- CDC20B | c.1058G>A p.R353H | Missense Mutation (SNP) | VAF 86/278 reads (31%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs140191094, COSV57049673; called by muse, mutect2, varscan2
- CLPSL1 | c.184G>A p.A62T | Missense Mutation (SNP) | VAF 66/306 reads (22%) | SIFT tolerated (0.52); PolyPhen benign (0.006); catalogued as COSV65814701; called by muse, mutect2, varscan2
- COL18A1 | c.2926G>A p.A976T (on ENST00000359759 / NM_130444.3; = p.A741T on NM_030582.4) | Missense Mutation (SNP) | VAF 70/234 reads (30%) | SIFT tolerated (0.46); PolyPhen benign (0.327); catalogued as rs777192146; called by muse, mutect2, varscan2
- DAZAP2 | c.137A>G p.Y46C | Missense Mutation (SNP) | VAF 53/133 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as rs1489433492; called by muse, mutect2, varscan2
- FAM47C | c.956G>A p.R319H | Missense Mutation (SNP) | VAF 147/428 reads (34%) | SIFT tolerated (0.71); PolyPhen benign (0.029); catalogued as rs142244745; called by muse, mutect2, varscan2
- KCNS1 | c.782G>A p.R261H | Missense Mutation (SNP) | VAF 90/218 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.374); catalogued as rs1437506774; called by muse, mutect2, varscan2
- LHX9 | c.442C>T p.R148C | Missense Mutation (SNP) | VAF 45/148 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.219); catalogued as COSV61329835; called by muse, mutect2, varscan2
- PIEZO2 | c.4436G>A p.R1479Q | Missense Mutation (SNP) | VAF 39/96 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs903681379, COSV100128741; called by muse, mutect2, varscan2
- PRDM9 | c.1843C>T p.R615W | Missense Mutation (SNP) | VAF 116/451 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57001967; called by muse, varscan2
- RUSC2 | c.3394_3396del p.I1132del | In Frame Del (DEL) | VAF 20/57 reads (35%) | catalogued as rs1170690908; called by pindel, varscan2
- SCLT1 | c.1187G>A p.R396Q | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as rs904186727, COSV55404690; called by muse, mutect2, varscan2
- SDK2 | c.3515G>A p.R1172H | Missense Mutation (SNP) | VAF 124/386 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.652); catalogued as rs145582973; called by muse, mutect2, varscan2
- SHISA3 | c.403C>T p.R135C | Missense Mutation (SNP) | VAF 110/350 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs761118083, COSV59979508; called by muse, mutect2, varscan2
- SYT16 | c.761G>A p.R254H | Missense Mutation (SNP) | VAF 38/123 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs201294056, COSV70856512; called by muse, mutect2, varscan2
- TTN | c.390C>G p.I130M | Missense Mutation (SNP) | VAF 23/71 reads (32%) | PolyPhen probably damaging (0.994); catalogued as COSV100594758; called by muse, mutect2, varscan2
- VPS16 | c.1206C>T p.A402= | Splice Region (SNP) | VAF 128/582 reads (22%) | catalogued as rs1225443675, COSV66793153; called by muse, mutect2, varscan2
- ZFR2 | c.2618G>A p.R873Q | Missense Mutation (SNP) | VAF 67/181 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.627); catalogued as rs770396423, COSV53600657; called by muse, mutect2, varscan2
- ZNF710 | c.1657G>A p.G553R | Missense Mutation (SNP) | VAF 11/146 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1315758279, COSV51566332; called by muse, mutect2
- ZNF829 | c.367C>T p.H123Y | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT tolerated (0.94); PolyPhen benign (0.012); catalogued as rs1354336301; called by muse, mutect2
- AHNAK | c.4510C>A p.P1504T | Missense Mutation (SNP) | VAF 165/294 reads (56%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- B4GALNT1 | c.380C>A p.S127* | Nonsense Mutation (SNP) | VAF 68/1364 reads (5%) | called by muse, mutect2
- CLEC7A | c.43T>C p.Y15H | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DEPDC5 | c.1287+1G>A p.X429_splice | Splice Site (SNP) | VAF 21/75 reads (28%) | called by muse, mutect2, varscan2
- DOCK4 | c.1168G>T p.G390* | Nonsense Mutation (SNP) | VAF 43/245 reads (18%) | called by muse, mutect2, varscan2
- HDAC2 | c.1392A>C p.E464D | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- HDAC8 | c.352G>A p.A118T | Missense Mutation (SNP) | VAF 57/195 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- IER3 | c.376T>A p.S126T | Missense Mutation (SNP) | VAF 93/276 reads (34%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- LMLN | c.949A>G p.S317G | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- MALRD1 | c.5375T>C p.V1792A | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2, varscan2
- METTL2B | c.686A>G p.D229G | Missense Mutation (SNP) | VAF 10/148 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.924); called by muse, mutect2
- OR5H1 | c.814A>G p.M272V | Missense Mutation (SNP) | VAF 66/294 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PLXNB3 | c.3583T>A p.C1195S | Missense Mutation (SNP) | VAF 92/393 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- RYR3 | c.5326G>C p.E1776Q | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.071); called by muse, mutect2
- TEX13C | c.167A>T p.D56V | Missense Mutation (SNP) | VAF 56/196 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TGM6 | c.1531C>A p.L511M | Missense Mutation (SNP) | VAF 148/472 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- TGS1 | c.1623C>G p.H541Q | Missense Mutation (SNP) | VAF 59/167 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- WASF1 | c.1234G>T p.V412F | Missense Mutation (SNP) | VAF 38/89 reads (43%) | SIFT tolerated (0.71); PolyPhen benign (0.058); called by muse, mutect2
- WWOX | c.591C>A p.F197L | Missense Mutation (SNP) | VAF 127/234 reads (54%) | SIFT tolerated (0.05); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- ZIC3 | c.401G>A p.G134D | Missense Mutation (SNP) | VAF 61/173 reads (35%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.704); called by muse, mutect2, varscan2
- ZNF862 | c.1048C>G p.L350V | Missense Mutation (SNP) | VAF 94/351 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- ACOX2 | c.1395G>A p.T465= | Silent (SNP) | VAF 68/194 reads (35%) | catalogued as rs1361574689; called by muse, mutect2, varscan2
- CD163L1 | c.1065C>T p.N355= | Silent (SNP) | VAF 92/264 reads (35%) | catalogued as rs369551730; called by muse, mutect2, varscan2
- CNTNAP2 | c.18C>T p.R6= | Silent (SNP) | VAF 66/295 reads (22%) | catalogued as COSV62265327; called by muse, mutect2, varscan2
- EPHB1 | c.915C>T p.T305= | Silent (SNP) | VAF 88/251 reads (35%) | catalogued as rs371516686; called by muse, mutect2, varscan2
- FRRS1 | c.156C>T p.Y52= | Silent (SNP) | VAF 62/190 reads (33%) | catalogued as rs756818505; called by muse, mutect2, varscan2
- FYB1 | c.6G>A p.A2= | Silent (SNP) | VAF 48/137 reads (35%) | catalogued as rs774770343, COSV60942303; called by mutect2, varscan2
- MAGEB6 | c.387C>T p.N129= | Silent (SNP) | VAF 74/321 reads (23%) | catalogued as rs183964860, COSV66871858; called by muse, mutect2, varscan2
- MAGEE1 | c.669C>T p.S223= | Silent (SNP) | VAF 79/320 reads (25%) | catalogued as COSV100819393; called by muse, mutect2, varscan2
- MESP2 | c.654G>A p.A218= | Silent (SNP) | VAF 9/107 reads (8%) | catalogued as rs1239001576; called by muse, mutect2
- NCR1 | c.504C>T p.Y168= | Silent (SNP) | VAF 100/297 reads (34%) | catalogued as rs765774550, COSV52555417, COSV52555583; called by muse, varscan2
- NEFM | c.2484C>T p.G828= | Silent (SNP) | VAF 122/326 reads (37%) | catalogued as rs555106103; called by muse, mutect2, varscan2
- NOD2 | c.126C>G p.V42= | Silent (SNP) | VAF 99/140 reads (71%) | called by muse, mutect2, varscan2
- PLAT | c.525C>T p.N175= | Silent (SNP) | VAF 35/90 reads (39%) | catalogued as rs1326934341; called by muse, mutect2
- PTPDC1 | c.192G>A p.K64= (on ENST00000375360 / NM_177995.3; = p.K116= on NM_152422.4) | Silent (SNP) | VAF 60/208 reads (29%) | called by muse, mutect2, varscan2
- RIOX1 | c.270C>T p.D90= | Silent (SNP) | VAF 38/204 reads (19%) | called by muse, mutect2, varscan2
- RPGRIP1 | c.924C>A p.L308= | Silent (SNP) | VAF 4/52 reads (8%) | called by muse, mutect2
- SOX17 | c.513C>T p.G171= | Silent (SNP) | VAF 78/229 reads (34%) | catalogued as rs766423684; called by muse, mutect2, varscan2
- TCHH | c.4017C>T p.R1339= | Silent (SNP) | VAF 96/261 reads (37%) | called by muse, mutect2, varscan2
- ZDHHC20 | c.51G>A p.V17= | Silent (SNP) | VAF 38/160 reads (24%) | called by muse, mutect2, varscan2
- ABCA4 | c.6282+225C>T | Intron (SNP) | VAF 98/236 reads (42%) | catalogued as rs1389779112; called by muse, mutect2, varscan2
- AL021937.5 | n.22C>A | RNA (SNP) | VAF 24/67 reads (36%) | called by muse, mutect2, varscan2
- ANXA2P2 | n.104C>A | RNA (SNP) | VAF 95/275 reads (35%) | called by muse, mutect2, varscan2
- BTK | c.-21G>T | 5'UTR (SNP) | VAF 12/296 reads (4%) | catalogued as COSV100437239; called by muse, mutect2
- FAM20A | c.*1076del | 3'UTR (DEL) | VAF 56/216 reads (26%) | catalogued as rs1568713203; called by mutect2, pindel, varscan2
- MIR143 | n.89G>A | RNA (SNP) | VAF 30/116 reads (26%) | called by muse, mutect2, varscan2
- PHYH | c.246-19T>G | Intron (SNP) | VAF 78/144 reads (54%) | called by muse, mutect2, varscan2
- PSG3 | c.*6G>A | 3'UTR (SNP) | VAF 50/146 reads (34%) | catalogued as rs761028412; called by muse, mutect2, varscan2
- SLIT3 | c.198-12203C>A | Intron (SNP) | VAF 33/93 reads (35%) | called by muse, mutect2, varscan2
- SNRNP40 | c.-36C>G | 5'UTR (SNP) | VAF 18/55 reads (33%) | catalogued as rs775006466; called by muse, varscan2
